CCDI case PBCLRT — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/1752a6db-ddd6-4843-8391-0165450e9d00

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 2.0 years (731 days).

Biospecimens (3 samples)
- Sample 0DWGIZ: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DWGJG: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DWGK0: Tissue type: Tumor; Specimen type: Solid Tissue.
